Somatic mutation profile of tumor specimen 0DMKL5 from CCDI case PBBXWI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.1 years (3,325 days).
Specimen 0DMKL5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7da63fde-21d0-47ab-a449-00bd594bb867.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMKKF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0fc015f-df64-4ab8-b39e-769e20e7eb95

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 2, Missense Mutation 2, 3'UTR 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STON2 | c.2055G>T p.R685S (on ENST00000649389 / NM_001366849.2; = p.R628S on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV50845568; called by muse, mutect2
- PLPP2 | c.86A>G p.N29S | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.01); called by muse, mutect2
- SLC6A8 | c.262+5G>T | Splice Region (SNP) | VAF 3/24 reads (13%) | called by muse, varscan2
- GID4 | c.-47C>G | 5'UTR (SNP) | VAF 11/98 reads (11%) | catalogued as rs865971612; called by mutect2, varscan2
- HMG20B | c.472+35C>A | Intron (SNP) | VAF 5/55 reads (9%) | catalogued as rs1362730924; called by muse, mutect2
- P2RX4 | c.135-276G>C | Intron (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- TRARG1 | c.*2617C>A | 3'UTR (SNP) | VAF 3/17 reads (18%) | called by muse, varscan2
